Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-5682, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-5682-01A (Primary Tumor).

DIAGNOSIS

(A) LEFT KIDNEY AND ADRENAL GLAND:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL TYPE), FUHRMAN'S NUCLEAR GRADE 4.
TUMOR INVOLVING RENAL VEIN.

TUMOR MEASURES 6.0 CM IN MAXIMUM DIMENSION.

Vascular, ureteral and soft tissue margins, free of tumor.

Adrenal gland, no tumor present.

GROSS DESCRIPTION

(A) LEFT KIDNEY AND ADRENAL GLAND - A left kidney (12.0 x 6.0 x 6.0 cm), a portion of left renal vein (4.0 cm in length), portion of ureter (11.0 cm in length), and portion of renal artery (1.0 cm in length). Also, received is a separate fragment of fibroadipose tissue (9.0 x 3.5 x 1.5 cm) that contains the adrenal gland (4.0 x 1.0 x 0.7 cm).

In the upper pole of the kidney is a lobular bright-yellow mass (6.0 x 3.5 x 4.0 cm). The mass appears to be completely surrounded by kidney parenchyma. It does not involve the perinephric adipose tissue. The tumor does extend into the renal sinus and involves the renal vein within the hilum of the kidney. The tumor within the renal vein is located at 2.0 cm from the renal vein margin. A portion of the tumor appears to be firm and white.

The uninvolved renal parenchyma, adrenal gland and the perinephric adipose tissue appear unremarkable.

A portion of tumor and normal kidney is submitted to the Tissue Bank. A portion of the tumor including the right fibrous area is submitted for

SECTION CODE: A1, renal vein, artery and ureter margin, en face; A2, A3, tumor adherent to renal vein; A4, tumor within the renal pelvis; A5-A7, representative sections of tumor to include renal capsule and adjacent normal parenchyma; A8, white fibrous area of tumor; A9, tumor in renal pelvis; A10, representative section of tumor; A11, representative section of uninvolved kidney; A12, representative sections of adrenal gland; A13, hilar tissue.

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-83123

Source: NCI Genomic Data Commons file 3160b93c-53fb-44e5-b0ce-a45fcb146e89 (TCGA-CJ-5682.06855541-6550-4EFB-9B3F-D8A3F9888386.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).